Somatic mutation profile of tumor specimen TCGA-SY-A9G0-01A (aliquot TCGA-SY-A9G0-01A-12D-A38G-08) from TCGA case TCGA-SY-A9G0, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 82.7 years (30,205 days).
Specimen TCGA-SY-A9G0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8aacf36a-607d-4916-b02e-26e427d61399.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SY-A9G0-10A (Blood Derived Normal), aliquot TCGA-SY-A9G0-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb155cd1-9c2b-4202-a6be-f69451b323bc

The open-access MAF lists 53 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 11, Nonsense Mutation 6, Splice Site 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABR | c.1354G>C p.E452Q (on ENST00000302538 / NM_021962.5; = p.E415Q on NM_001092.5) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV52142869; called by muse, mutect2
- ADGRG4 | c.3400G>A p.D1134N | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54951668; called by muse, mutect2, varscan2
- BIRC3 | c.1751C>G p.S584C | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99680125; called by muse, mutect2
- BRD7 | c.1652G>C p.R551T | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV54265041, COSV54266823; called by muse, mutect2, varscan2
- C2CD3 | c.2891G>C p.R964T | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58090948; called by muse, mutect2
- CFAP65 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as rs763060434, COSV55389699; called by muse, mutect2, varscan2
- CHL1 | c.2252G>A p.W751* (on ENST00000397491 / NM_001253387.1; = p.W767* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99851944; called by muse, mutect2
- CRYBB2 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | catalogued as rs1209985177, COSV101236760; called by muse, mutect2, varscan2
- DPP4 | c.493-1G>A p.X165_splice | Splice Site (SNP) | VAF 9/124 reads (7%) | catalogued as COSV62105663; called by muse, mutect2
- DYSF | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV50278452; called by muse, mutect2, varscan2
- ERI1 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV99141402; called by muse, mutect2
- FAM131B | c.231G>A p.M77I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV68125683; called by muse, mutect2, varscan2
- FAM83C | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as rs538680638, COSV65582351, COSV65583477; called by muse, mutect2, varscan2
- FBXO40 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV57521905; called by muse, mutect2, varscan2
- FGFR2 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs374993905; ClinVar: not provided; called by muse, mutect2
- GNA13 | c.599G>C p.R200T | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV71474364, COSV71474492; called by muse, mutect2
- GPR179 | c.6130G>C p.E2044Q (on ENST00000621958; = p.E2043Q on NM_001004334.4) | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.596); catalogued as rs1355853079; called by muse, mutect2, varscan2
- HKDC1 | c.2650C>T p.R884* | Nonsense Mutation (SNP) | VAF 9/148 reads (6%) | catalogued as rs375835998; called by muse, mutect2
- IGSF10 | c.1429A>T p.R477W | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV56782714; called by muse, mutect2
- IP6K3 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs371705640, COSV99540096; called by muse, mutect2, varscan2
- KIF1A | c.1334C>G p.A445G | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57484757; called by muse, mutect2, varscan2
- KRT28 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs763555183, COSV60683964; called by muse, mutect2, varscan2
- LRRIQ3 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV63041921; called by muse, mutect2, varscan2
- MAP3K4 | c.1855C>T p.L619F | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100815598; called by muse, mutect2
- MCEE | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 12/158 reads (8%) | catalogued as COSV99731231; called by muse, mutect2
- MIA3 | c.1796C>G p.A599G | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs545848838, COSV60510689; called by muse, mutect2, varscan2
- MICALL1 | c.1613C>G p.S538* | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | catalogued as COSV53243162, COSV99317493; called by muse, mutect2, varscan2
- NAA50 | c.503A>G p.D168G | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV53786113; called by muse, mutect2, varscan2
- NEK2 | c.605T>G p.L202W | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65355418; called by muse, mutect2, varscan2
- OR4C46 | c.441G>A p.W147* | Nonsense Mutation (SNP) | VAF 19/114 reads (17%) | catalogued as rs1446043123, COSV100060887, COSV100060997; called by muse, mutect2, varscan2
- OR4K14 | c.619C>A p.L207I | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.173); catalogued as COSV100520494; called by muse, mutect2
- PCDHGA6 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.779); catalogued as rs779058063, COSV99543984; called by muse, mutect2
- RNF185 | c.331C>G p.Q111E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.585); catalogued as COSV99839576; called by muse, mutect2, varscan2
- SCRIB | c.691C>G p.R231G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57583884; called by muse, mutect2, varscan2
- SGPL1 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64591231; called by muse, mutect2
- SPAG5 | c.1232G>C p.S411T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV58800495; called by muse, mutect2, varscan2
- TYRO3 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55481745; called by muse, mutect2
- TYRP1 | c.622T>A p.F208I | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV66357770; called by muse, mutect2
- ZNF540 | c.702G>C p.Q234H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.858); catalogued as COSV57108389, COSV57110045; called by muse, mutect2, varscan2
- KDM6A | c.3406_3407insATA p.Y1135_M1136insN | In Frame Ins (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- TPTE | c.565A>G p.R189G (on ENST00000618007 / NM_199261.4; = p.R171G on NM_199259.4) | Missense Mutation (SNP) | VAF 17/284 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.5988C>T p.S1996= | Silent (SNP) | VAF 27/141 reads (19%) | catalogued as rs546503944, COSV51842519; called by muse, mutect2, varscan2
- CHD6 | c.6036A>T p.T2012= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV64688905; called by muse, mutect2, varscan2
- FAM124A | c.156C>T p.I52= (on ENST00000322475 / NM_001242312.2; = p.I88= on NM_145019.4) | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV54474889; called by muse, mutect2, varscan2
- GDA | c.837C>T p.H279= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs748189548, COSV52991225; called by mutect2, varscan2
- HMHB1 | c.93G>C p.L31= | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as COSV56869253; called by muse, mutect2, varscan2
- LRRC40 | c.1662C>G p.L554= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as COSV63941740; called by muse, mutect2, varscan2
- MAP3K4 | c.1854T>G p.V618= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV100815597; called by muse, mutect2
- NDUFAF4 | c.153A>G p.K51= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV60213809; called by muse, mutect2, varscan2
- PCDHA9 | c.1509G>A p.S503= | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as rs782166017, COSV65324248; called by muse, mutect2, varscan2
- SOCS6 | c.1245T>C p.R415= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV67546072; called by muse, mutect2, varscan2
- UNK | c.1378C>T p.L460= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as COSV99505412; called by muse, mutect2
- HMGB1P1 | n.248G>A | RNA (SNP) | VAF 17/137 reads (12%) | called by muse, mutect2, varscan2
